Somatic mutation profile of tumor specimen TCGA-AD-6899-01A (aliquot TCGA-AD-6899-01A-11D-1924-10) from TCGA case TCGA-AD-6899, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 84.0 years (30,693 days).
Specimen TCGA-AD-6899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d89c579-2dbc-4694-9336-e1fddbf28112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6899-10A (Blood Derived Normal), aliquot TCGA-AD-6899-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/707e93da-6771-40d5-a659-c00d52a03846

The open-access MAF lists 169 somatic variants for this specimen: 118 protein-altering or splice-affecting, 48 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 48, Nonsense Mutation 7, Frame Shift Del 2, RNA 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT10 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs58075662, CM920396, CM930453, CM941007, COSV54091758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 95/227 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684436, COSV61688043; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 17/27 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs149224164, COSV61820315; called by muse, mutect2, varscan2
- ANKMY1 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV56042040; called by muse, varscan2
- APC | c.3569del p.S1190Yfs*75 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as COSV57327178, COSV99971414; called by mutect2, pindel, varscan2
- ARHGAP5 | c.3529G>A p.D1177N | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV61539682; called by muse, mutect2
- ATM | c.8762C>T p.T2921M | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs730881329, COSV53726751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1B1 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52272481; called by muse, mutect2, varscan2
- BTBD17 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100945242; called by muse, mutect2
- C8A | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143726641, COSV63484861; called by muse, mutect2, varscan2
- CACNA1C | c.2954G>T p.G985V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV59780008; called by muse, mutect2, varscan2
- CBY2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs778108248, COSV60120103; called by muse, mutect2, varscan2
- CCDC18 | c.1813G>C p.E605Q (on ENST00000343253 / NM_001306076.1; = p.E606Q on NM_206886.4) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755044272, COSV58148598; called by muse, mutect2, varscan2
- CCDC93 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs531145241, COSV60124703; called by muse, mutect2, varscan2
- CDH12 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs371189490; called by muse, mutect2, varscan2
- CKAP2 | c.2033A>G p.Y678C (on ENST00000378037 / NM_001098525.2; = p.Y677C on NM_018204.5) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.35); catalogued as COSV51625010; called by muse, mutect2, varscan2
- CLDN16 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV99289988, COSV99289996; called by muse, mutect2, varscan2
- DAGLB | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV51707244; called by muse, mutect2, varscan2
- DCAF12 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1011181576, COSV63514078; called by muse, mutect2, varscan2
- DCLK1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as rs778679656, COSV55206705; called by muse, mutect2, varscan2
- DGKZ | c.926G>A p.R309K (on ENST00000454345 / NM_001105540.2; = p.R120K on NM_003646.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58996345; called by muse, mutect2, varscan2
- DIAPH2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 57/73 reads (78%) | catalogued as COSV61265269; called by muse, mutect2, varscan2
- DIAPH3 | c.1832C>T p.P611L (on ENST00000400324 / NM_001042517.2; = p.P348L on NM_030932.3) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs754490079, COSV57382798, COSV99934113; called by muse, mutect2, varscan2
- DMBT1 | c.3030C>G p.Y1010* (on ENST00000338354 / NM_001377530.1; = p.Y511* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV57565831; called by muse, mutect2, varscan2
- DSCAM | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs201979167; called by muse, mutect2, varscan2
- DSE | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV59067834; called by muse, mutect2, varscan2
- EVPL | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as rs773551297, COSV56916825; called by muse, mutect2, varscan2
- EYS | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.525); catalogued as COSV60986188, COSV61001761; called by muse, mutect2, varscan2
- F12 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV53693423; called by muse, varscan2
- FAM229B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV100898104, COSV64087635; called by muse, mutect2, varscan2
- FCGBP | c.6260G>A p.R2087Q | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs1188808248; called by muse, mutect2
- FLT3 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs587778369, COSV54047766, COSV54049596; ClinVar: not provided; called by muse, mutect2, varscan2
- FRMPD4 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as COSV66224624; called by muse, mutect2, varscan2
- GJA8 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM166501, COSV53790907, COSV99569031; called by muse, mutect2, varscan2
- GPC6 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771182029, COSV65541167; called by muse, mutect2, varscan2
- GZMK | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.035); catalogued as COSV50249222; called by muse, mutect2, varscan2
- HSPA12A | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs782115853, COSV65024134; called by muse, mutect2, varscan2
- HYDIN | c.12576G>T p.E4192D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.229); catalogued as rs1443992117, COSV101124913; called by muse, mutect2, varscan2
- IRX2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388711196, COSV57414078; called by muse, mutect2, varscan2
- KIAA0586 | c.2939A>T p.D980V (on ENST00000619416 / NM_001244190.2; = p.D919V on NM_014749.5) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99707568; called by muse, mutect2, varscan2
- KIR3DL3 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs544733307, COSV52546043; called by muse, mutect2, varscan2
- KMT2C | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100068273, COSV51522527; called by muse, mutect2, varscan2
- KRT84 | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs756555748, COSV57774008; called by muse, mutect2, varscan2
- KRTAP19-4 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.099); catalogued as rs754492060, COSV100478455, COSV61858768; called by muse, mutect2, varscan2
- MACF1 | c.4892C>T p.T1631I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs745526080, COSV99241636; called by muse, mutect2, varscan2
- MAP1S | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as rs1317857813, COSV60724894; called by muse, mutect2, varscan2
- MCM3AP | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs1242854199, COSV52446368; called by muse, mutect2, varscan2
- MMP9 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774687719, COSV63434571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC17 | c.11692C>G p.P3898A | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as COSV100074161, COSV60306254; called by muse, mutect2, varscan2
- NCKAP5 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100490330, COSV58479071; called by muse, mutect2, varscan2
- NDN | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100086249; called by muse, mutect2
- NDUFS2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV63488885; called by muse, mutect2, varscan2
- NES | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1458091128, COSV63963169; called by muse, mutect2, varscan2
- NOSIP | c.235_237del p.K79del | In Frame Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751353745; called by pindel, varscan2
- NOVA1 | c.960T>G p.N320K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99946634; called by muse, mutect2, varscan2
- NR5A1 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as rs780199277, COSV65295441; called by muse, mutect2, varscan2
- NTNG1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53977286; called by muse, mutect2, varscan2
- NUGGC | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs377099582; called by muse, mutect2, varscan2
- OR4C46 | c.341C>A p.T114N | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV60219406; called by muse, mutect2, varscan2
- OR4D10 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV73260226; called by muse, mutect2, varscan2
- PAH | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV61020922; called by muse, mutect2, varscan2
- PCDHA9 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as rs782658418, COSV100969102; called by muse, mutect2, varscan2
- PCDHGA4 | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as rs772395094, COSV54047970; called by muse, mutect2, varscan2
- PCSK1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.62); catalogued as rs758046584, COSV60733679; called by muse, mutect2, varscan2
- PEX14 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV63063980; called by muse, mutect2, varscan2
- PIWIL4 | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs777500348, COSV100133071; called by muse, mutect2, varscan2
- PLCZ1 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770563339, COSV56850134; called by muse, mutect2, varscan2
- PPP4R3B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as rs770258878, COSV55404083; called by muse, mutect2
- PRSS12 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56611076; called by muse, mutect2, varscan2
- PSD3 | c.1321T>A p.Y441N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV58981068; called by muse, mutect2, varscan2
- RALGDS | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs745523786, COSV64429960; called by muse, varscan2
- RBFOX1 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV60987121; called by muse, mutect2, varscan2
- RGMA | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs752421802, COSV61232765; called by muse, mutect2, varscan2
- RIMKLB | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as rs1425389132, COSV55240435; called by muse, mutect2, varscan2
- RYR3 | c.14414A>G p.H4805R (on ENST00000389232; = p.H4806R on NM_001036.6) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1280070158, COSV101212061; called by muse, mutect2, varscan2
- SCN2A | c.5422G>A p.D1808N | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs767541516, COSV51849495; called by muse, mutect2
- SIX4 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1210952390, COSV99381980; called by muse, mutect2, varscan2
- SLC35E3 | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60118599; called by muse, mutect2, varscan2
- SLC4A8 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV60658927; called by muse, mutect2, varscan2
- SLITRK3 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs756131997, COSV53845789; called by muse, mutect2, varscan2
- SMARCA2 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs865840815, COSV100570457, COSV61807785; called by muse, mutect2, varscan2
- SP110 | c.752-1G>C p.X251_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as COSV51279328; called by muse, mutect2, varscan2
- SPAG9 | c.3134G>A p.R1045Q (on ENST00000262013 / NM_001130528.3; = p.R1031Q on NM_003971.6) | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs1302094745, COSV56245120; called by muse, mutect2, varscan2
- SPEG | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.028); catalogued as COSV56681032; called by muse, mutect2, varscan2
- SPI1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV57048403; called by muse, mutect2, varscan2
- SPSB4 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV60150928; called by muse, mutect2, varscan2
- SRC | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs1358694181, COSV62441465; called by muse, mutect2, varscan2
- SRGAP2 | c.2275C>T p.R759W (on ENST00000624873 / NM_001170637.4; = p.R760W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99832490; called by muse, mutect2, varscan2
- STK10 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as COSV51579862; called by muse, mutect2, varscan2
- SVEP1 | c.5317G>A p.V1773I | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52844827; called by muse, mutect2, varscan2
- TBXAS1 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs761419784, COSV54955519; called by muse, mutect2, varscan2
- TCAIM | c.878G>A p.W293* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV61243025; called by muse, mutect2, varscan2
- TCF12 | c.1905A>G p.R635= | Splice Region (SNP) | VAF 33/80 reads (41%) | catalogued as rs140371989; called by muse, mutect2, varscan2
- TENT5B | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006804, COSV56694132; called by muse, mutect2, varscan2
- THADA | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100368033; called by muse, mutect2, varscan2
- THEM5 | c.369A>C p.E123D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV64313292; called by muse, mutect2, varscan2
- TMEM135 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202089067, COSV59707425; called by muse, mutect2, varscan2
- TRPM3 | c.692G>A p.R231H (on ENST00000357533 / NM_001366142.2; = p.R76H on NM_020952.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs766892514, COSV62467501; called by muse, mutect2, varscan2
- TSHZ3 | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs541898039, COSV53673019; called by muse, mutect2, varscan2
- URI1 | c.747A>T p.E249D | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV56353563; called by muse, mutect2, varscan2
- USP5 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1555128069, COSV99977281; called by muse, mutect2, varscan2
- VNN1 | c.1272G>T p.M424I | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV63390315; called by muse, mutect2, varscan2
- ZC3H4 | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV53417771; called by muse, mutect2, varscan2
- ZMYM1 | c.1638G>C p.Q546H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV63253236, COSV63254106; called by muse, mutect2, varscan2
- ZNF266 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs769084393, COSV63222205; called by muse, mutect2, varscan2
- ZNF385B | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61182112; called by muse, mutect2, varscan2
- ZNF585A | c.1919G>C p.G640A (on ENST00000292841 / NM_001288800.2; = p.G585A on NM_152655.3) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53065867, COSV99492781; called by muse, mutect2, varscan2
- ZNF616 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57513732; called by muse, mutect2, varscan2
- ZNF701 | c.970C>A p.L324I (on ENST00000301093; = p.L258I on NM_018260.3) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99990701; called by muse, mutect2
- HNF1B | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.346); called by muse, mutect2
- HNF1B | c.581C>G p.T194R | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.102); called by muse, mutect2
- LTK | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by mutect2, varscan2
- MYO3A | c.2968del p.H990Ifs*9 | Frame Shift Del (DEL) | VAF 52/224 reads (23%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9854dup p.Y3286Ifs*70 | Frame Shift Ins (INS) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- ALG1L | c.57C>G p.L19= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as COSV61076846; called by muse, mutect2
- ANK1 | c.2346C>T p.V782= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99224137; called by muse, mutect2, varscan2
- ANKZF1 | c.102C>T p.H34= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV60135795; called by muse, mutect2, varscan2
- ASMTL | c.546C>T p.G182= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs775357494, COSV101187679; called by muse, mutect2
- BANK1 | c.696A>T p.S232= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV59851034; called by muse, mutect2, varscan2
- CCDC62 | c.813G>A p.A271= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs756265250, COSV53430813; called by muse, mutect2, varscan2
- CCDC93 | c.600T>C p.A200= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV60124695; called by muse, mutect2, varscan2
- CFTR | c.2172C>T p.I724= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as rs368599862; called by muse, mutect2, varscan2
- CLSTN2 | c.1785G>A p.T595= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as rs759692635, COSV71725612; called by muse, mutect2, varscan2
- CORO1B | c.459C>T p.C153= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs369102459; called by muse, mutect2, varscan2
- CTNND2 | c.450G>T p.L150= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58933540; called by muse, mutect2, varscan2
- CTNND2 | c.117C>T p.N39= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs779081326, COSV58933547; called by muse, mutect2, varscan2
- DEGS2 | c.651C>T p.F217= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV59784237, COSV59784368; called by muse, mutect2
- DIRAS1 | c.48C>T p.G16= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1390866824, COSV60216721; called by muse, mutect2, varscan2
- FAM214B | c.135C>T p.P45= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs760280849, COSV59717778; called by muse, mutect2, varscan2
- FZD7 | c.879G>A p.S293= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV53811738; called by muse, mutect2, varscan2
- GFRA4 | c.687C>T p.C229= (on ENST00000319242 / NM_145762.3; = p.C199= on NM_022139.4) | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV51775796; called by muse, mutect2, varscan2
- GIMAP7 | c.333C>T p.T111= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs144054418, COSV57960664; called by muse, mutect2, varscan2
- GIN1 | c.573T>C p.N191= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV67537911; called by muse, mutect2, varscan2
- KCNK5 | c.46C>T p.L16= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs748059487, COSV63989530; called by muse, mutect2, varscan2
- KPTN | c.453C>G p.V151= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100583369; called by muse, mutect2
- LRRK2 | c.7167C>T p.C2389= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs780498854, COSV54150990; called by muse, mutect2, varscan2
- LYST | c.10416C>T p.Y3472= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs757982705, COSV67715105; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCU | c.957A>G p.Q319= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1373913464, COSV100849081; called by muse, mutect2
- MIB2 | c.2203C>T p.L735= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- MYH8 | c.3405G>A p.A1135= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs78443907; called by muse, mutect2, varscan2
- MYLK3 | c.1533G>A p.A511= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs756004337, COSV67367268; called by muse, mutect2, varscan2
- NEK6 | c.339C>T p.I113= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs765205974, COSV57220884; called by mutect2, varscan2
- NGRN | c.21C>T p.L7= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs750810675, COSV58961746; called by muse, mutect2, varscan2
- NLRP6 | c.1089G>A p.R363= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV56462344; called by muse, mutect2, varscan2
- NR2C1 | c.1491C>T p.Y497= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1200470948, COSV58010415; called by muse, mutect2, varscan2
- NRAP | c.2301C>T p.D767= (on ENST00000359988 / NM_001322945.2; = p.D732= on NM_006175.4) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs775235880, COSV63494579; called by muse, mutect2, varscan2
- NSD2 | c.2418C>T p.I806= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1302163799, COSV100372884; called by muse, mutect2
- OR2A12 | c.870C>T p.S290= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV68821058; called by muse, mutect2, varscan2
- OTOF | c.843C>T p.D281= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs368728682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R4 | c.1710T>A p.R570= | Silent (SNP) | VAF 90/177 reads (51%) | catalogued as COSV63239854; called by muse, mutect2, varscan2
- POMGNT1 | c.531C>G p.V177= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV64341192; called by muse, mutect2, varscan2
- PRR22 | c.1044C>T p.T348= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs751884482, COSV57833404, COSV57833887; called by muse, mutect2, varscan2
- PRUNE2 | c.8943C>T p.C2981= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- RIMS2 | c.2406A>G p.P802= (on ENST00000666250 / NM_001348490.2; = p.P610= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs367730974; called by muse, mutect2, varscan2
- ROBO2 | c.177G>A p.T59= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs762225187, COSV59907559; called by muse, mutect2, varscan2
- RPRD1B | c.588T>G p.T196= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV65034199; called by muse, mutect2, varscan2
- SLC13A3 | c.1506G>C p.L502= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1568907154, COSV99286237; called by muse, mutect2
- SLC38A11 | c.81G>A p.L27= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV58056471; called by muse, mutect2, varscan2
- SPOCK3 | c.237C>T p.F79= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs768520189, COSV62717229, COSV62733609; called by muse, mutect2, varscan2
- TNC | c.4941C>T p.F1647= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs201689087, COSV60788203; called by muse, mutect2, varscan2
- TRGC1 | c.228G>A p.T76= | Silent (SNP) | VAF 98/239 reads (41%) | catalogued as rs562260133; called by muse, mutect2, varscan2
- UHMK1 | c.471G>A p.A157= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs767610803, COSV56421574; called by muse, mutect2, varscan2
- KIR3DX1 | n.533G>A | RNA (SNP) | VAF 19/41 reads (46%) | catalogued as rs757014625, COSV55598804; called by muse, mutect2, varscan2
- PKD1L2 | n.324C>T | RNA (SNP) | VAF 36/81 reads (44%) | catalogued as rs781143861; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185137G>A | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as rs771567004, COSV60946776, COSV60951877; called by muse, mutect2, varscan2
